Surgical pathology report (de-identified scan), TCGA case TCGA-FR-A3YO, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of North Carolina, specimen TCGA-FR-A3YO-06A (Metastatic).

[page 1 of 3]
ICD-O3
melanoma, NOS 872013

Site: CoxF-jejunum C17.1
Path-jejunum C17.1 6-6-12
RO

SURGICAL PATHOLOGY

Case Number :

Surgical Pathology Report

Accession #:

Reviewed (Initials)	Date Reviewed	

6/6/12

Diagnosis:

A: Proximal jejunum and splenic flexure, resection

- Two deposits of metastatic melanoma, 9.0 cm in greatest dimension, extensively invading through the walls of the jejunum and colon and extensively involving pericolic fat and mesentery
- Approximately 30% of the tumor is necrotic
- Block A6 will be sent for BRAF molecular analysis
- Proximal and distal en face margins are negative
- Metastatic melanoma also involves 2 out of 2 small mesenteric lymph nodes as many microscopic deposits (2/2)
- Extracapsular extension is not identified

B: Lymph node, mesenteric, removal

- Metastatic melanoma involving 1 out of 1 lymph nodes, with the largest diameter measuring 3.7 cm (1/1)
- Extracapsular extension is present
- Approximately 90% of the tumor is necrotic

Clinical History:

-year-old . with metastatic melanoma. ** Please do BRAF testing. **

Gross Description:

Received are two appropriately labeled containers.

Container A is additionally labeled "proximal jejunum and splenic flexure." It holds a 23.0 cm in length x 2.5-8.0 cm in diameter section of small bowel. The larger circumference area corresponds to portion of bowel distended by tumor (see below). The serosal surface of the bowel is pink/tan,

[page 2 of 3]
smooth and glistening without adhesions. The small bowel is received oriented by the surgeon with a suture marking the proximal small bowel. It is opened to reveal a 9.0 x 8.0 x 6.0 cm black/brown friable, partially necrotic mass located 2 cm from the proximal small bowel margin and 12 cm from the distal small bowel margin. Tumor invades into the muscularis propria. Although tumor is identified in adjacent soft tissue and large bowel haustral fat, no full thickness disruption of the small bowel is identified. A second 1.0 x 1.0 x 0.5 cm lesion is located 0.7 cm proximal to the larger lesion and is 1.5 cm from the proximal margin. The remainder of the small bowel surface is tan and undulating without grossly evident lesions.

A 17.0 x 2.2 cm segment of large bowel is matted to the small bowel. The external surface is partly a pink/tan serosal surface and partly yellow lobulated mesentery which is adherent to the small bowel. The specimen is opened along the serosal surface to reveal a lumen that is not involved grossly by tumor. The mucosal surface is pink/tan and undulating without grossly evident lesions. Serial sectioning through the large and small bowel reveals that the previously described tumor appears to abut but not invade into the muscularis propria of the large bowel. The proximal en face margin is 3.2 cm from the closest approach of tumor to the large bowel and the distal en face margin is 8.5 cm from the closest approach of tumor. Dissection of pericolic fat reveals a 0.8 x 0.7 x 0.5 cm lymph node candidate which is grossly involved by tumor.

Block summary:

[page 3 of 3]
A1 - proximal small bowel en face margin
A2 - distal small bowel en face margin
A3 - proximal large bowel en face margin
A4 - distal large bowel en face margin
A5 - transition to small bowel to tumor
A6 - tumor in relation to small bowel serosa
A7 - tumor transitioning to normal distal small bowel
A8-A10 - tumor in relation to large bowel
A11 - transition from smaller lesion to larger lesion
A12 - tumor involving haustra
A13 - one grossly involved lymph node candidate
A14-A15- additional sections of tumor in relation to small bowel wall

Tissue remains in formalin.

Container B is additionally labeled "mesenteric lymph node." It holds a 3.7 x 2.4 x 2.0 cm lymph node candidate. The cut surface reveals that the lymph node is grossly effaced by brown/black, soft, necrotic tumor. Representative sections are submitted in blocks B1-B2. Tissue remains in formalin.

Source: NCI Genomic Data Commons file 2f93af07-c6f4-44dc-87c2-064ee1ad8d47 (TCGA-FR-A3YO.1B823F22-738D-450F-A1D8-9A7840D316A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).